Somatic mutation profile of tumor specimen TCGA-C9-A47Z-01A (aliquot TCGA-C9-A47Z-01A-11D-A24D-08) from TCGA case TCGA-C9-A47Z, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 72.8 years (26,592 days).
Specimen TCGA-C9-A47Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fe16224-3c25-4557-8cd8-e214be335edd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C9-A47Z-10A (Blood Derived Normal), aliquot TCGA-C9-A47Z-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/098cd12a-f749-41ad-842c-bb21272962cd

The open-access MAF lists 116 somatic variants for this specimen: 88 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 26, Splice Site 3, Frame Shift Ins 2, Nonsense Mutation 2, Intron 1, 5'Flank 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCF1 | c.856G>A p.V286M (on ENST00000326195 / NM_001025091.2; = p.V248M on NM_001090.3) | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); catalogued as rs1422039008, COSV58230545; called by muse, mutect2, varscan2
- ACACB | c.4446+1G>C p.X1482_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100622166; called by muse, mutect2, varscan2
- ADD2 | c.1412C>A p.S471Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV100034423; called by muse, mutect2, varscan2
- AFF2 | c.36G>C p.L12F | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs782701728, COSV100648729; called by muse, varscan2
- AP4B1 | c.1472G>T p.C491F | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99870453; called by muse, mutect2, varscan2
- ARID2 | c.881G>T p.R294I | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57599678, COSV57606673, COSV57614708; called by muse, mutect2, varscan2
- ATF6 | c.1952C>G p.S651C | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100908973; called by muse, mutect2, varscan2
- ATP2A1 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs760705868, COSV100837032; called by muse, mutect2, varscan2
- B4GALNT1 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1363906394, COSV100246871; called by muse, mutect2, varscan2
- BMP5 | c.899T>G p.F300C | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100895680; called by muse, mutect2, varscan2
- CACNA1C | c.3589C>T p.R1197W | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs888326149, COSV100214323; called by muse, mutect2, varscan2
- CARD10 | c.2279G>T p.R760L | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.247); catalogued as COSV99324505; called by muse, mutect2, varscan2
- CCDC85A | c.1453G>T p.G485C | Missense Mutation (SNP) | VAF 18/25 reads (72%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.841); catalogued as rs780223971, COSV101339334; called by muse, mutect2, varscan2
- CCDC87 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100039693; called by muse, mutect2, varscan2
- CD1A | c.179A>G p.N60S | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs745776518, COSV99192127; called by muse, mutect2
- CDC42BPG | c.3730G>A p.G1244S | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs1171028334, COSV100711927; called by muse, mutect2, varscan2
- CDH9 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1340493492, COSV50251915; called by muse, mutect2, varscan2
- CFAP206 | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.134); catalogued as COSV99738980; called by muse, mutect2
- CFTR | c.2043A>T p.E681D | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV99133640; called by muse, mutect2, varscan2
- CGB3 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1472624570, COSV100642184; called by mutect2, varscan2
- CLSPN | c.2861C>T p.S954F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs747801015, COSV99230123; called by muse, mutect2, varscan2
- CPT1C | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV54922119; called by muse, mutect2, varscan2
- CRB1 | c.1438T>A p.C480S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM010800, CM010801, COSV100957604; called by muse, mutect2, varscan2
- CST1 | c.206G>A p.R69Q | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.54); PolyPhen benign (0.053); catalogued as rs3188305, COSV59055350; called by muse, mutect2, varscan2
- CTCFL | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV54774624, COSV99711958; called by muse, mutect2
- DNAH5 | c.4667A>G p.D1556G | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99443623; called by muse, mutect2, varscan2
- DOP1A | c.4434T>G p.D1478E | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV99380656; called by muse, mutect2, varscan2
- EZHIP | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 29/43 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.202); catalogued as COSV100539425; called by muse, mutect2, varscan2
- EZHIP | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.037); catalogued as COSV100539426; called by muse, mutect2, varscan2
- EZHIP | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57957073; called by muse, mutect2, varscan2
- FAM135B | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV99417433; called by muse, mutect2, varscan2
- FBLN7 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV100485397; called by muse, mutect2, varscan2
- FOSL1 | c.746G>C p.R249P | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100440782; called by muse, mutect2, varscan2
- FST | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56815477; called by muse, mutect2
- GABRA3 | c.633C>A p.S211R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100942395; called by muse, mutect2
- GK | c.1447G>T p.E483* (on ENST00000427190 / NM_001205019.2; = p.E477* on NM_000167.6) | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV100970327, COSV100970353; called by muse, mutect2, varscan2
- GOLPH3L | c.61A>T p.M21L | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99653561; called by muse, mutect2, varscan2
- H4C11 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV61826863; called by muse, mutect2, varscan2
- HDAC6 | c.3629A>T p.D1210V | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV100490487; called by muse, mutect2, varscan2
- HDAC9 | c.911T>A p.V304D | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.715); catalogued as COSV101285692; called by muse, mutect2, varscan2
- HERC1 | c.9778A>G p.I3260V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.847); catalogued as COSV101496282; called by muse, mutect2, varscan2
- HIRA | c.1963G>T p.V655L | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99599787; called by muse, mutect2, varscan2
- IFT122 | c.3058G>C p.D1020H (on ENST00000348417 / NM_052989.3; = p.D961H on NM_018262.4) | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV99958576; called by muse, mutect2, varscan2
- INIP | c.26-1G>A p.X9_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100954077; called by muse, mutect2, varscan2
- IVNS1ABP | c.357+2T>C p.X119_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV100832482; called by muse, mutect2, varscan2
- KCNC1 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56394773, COSV56395500; called by muse, mutect2, varscan2
- LHFPL5 | c.178G>A p.G60S | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100798909; called by muse, mutect2, varscan2
- LPXN | c.473C>T p.P158L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as rs200939192, COSV67718224; called by muse, mutect2, varscan2
- LRRN1 | c.1029G>T p.M343I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV100075952; called by muse, mutect2, varscan2
- LSR | c.580A>T p.R194W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100670318; called by muse, mutect2
- MAP2K2 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.95); catalogued as COSV53567845, COSV99501871; called by muse, mutect2, varscan2
- MARCHF4 | c.711G>T p.Q237H | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV99813973; called by muse, mutect2, varscan2
- MFAP4 | c.95G>C p.R32T | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs752492765, COSV100218737; called by muse, mutect2, varscan2
- MT3 | c.29C>T p.S10F | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1567334543, COSV99570458; called by muse, mutect2, varscan2
- MTOR | c.4888G>A p.V1630I | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV100815620; called by muse, mutect2, varscan2
- MYCBP2 | c.10613C>T p.A3538V (on ENST00000357337; = p.A3576V on NM_015057.5) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs748993015, COSV100628921; called by muse, mutect2, varscan2
- MYH3 | c.3503G>A p.R1168Q | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as rs558085793, COSV56861961; called by muse, mutect2, varscan2
- OR2M5 | c.62G>C p.S21T | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as COSV100822708; called by muse, mutect2, varscan2
- OR4B1 | c.131T>A p.V44D | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100535459; called by muse, mutect2, varscan2
- OR4N5 | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 48/132 reads (36%) | catalogued as COSV100373999; called by muse, mutect2, varscan2
- OR6K2 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); catalogued as COSV62743745; called by muse, mutect2, varscan2
- PCLO | c.5911G>A p.G1971S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100426369; called by muse, mutect2, varscan2
- PEX6 | c.2636A>G p.Q879R | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.101); catalogued as COSV99769393; called by muse, mutect2, varscan2
- PGAM1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.818); catalogued as COSV100602386; called by muse, mutect2, varscan2
- PLCB1 | c.3152A>T p.N1051I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.603); catalogued as COSV100569004; called by muse, mutect2, varscan2
- PLCG2 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as rs781016626, COSV63867611; called by muse, mutect2, varscan2
- PNLDC1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs745935275, COSV51706726, COSV51706896; called by muse, mutect2, varscan2
- PPFIA3 | c.101C>T p.T34M | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as COSV100494615; called by muse, mutect2, varscan2
- RTTN | c.6521A>G p.Q2174R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99730632; called by muse, mutect2, varscan2
- SCRIB | c.4111G>A p.E1371K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1026018447, COSV57593688; called by muse, mutect2, varscan2
- SHANK2 | c.2821G>A p.V941M | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs146332040; called by muse, mutect2, varscan2
- SLC5A1 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768831308, COSV99833132; called by muse, mutect2, varscan2
- SMARCA2 | c.2662C>A p.L888I | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV100570122; called by muse, mutect2, varscan2
- SPHKAP | c.1496C>A p.A499E | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs748375560, COSV100763574, COSV60883248; called by muse, mutect2, varscan2
- SYT9 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778982022, COSV59614771; called by muse, mutect2, varscan2
- SYTL4 | c.1046G>T p.G349V | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52172162, COSV99342582; called by muse, mutect2, varscan2
- TBX22 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs756913403, COSV100960557; called by muse, mutect2, varscan2
- TENM1 | c.5800C>T p.R1934W | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100948793; called by muse, mutect2, varscan2
- TNNI3K | c.2499C>G p.D833E | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.952); catalogued as COSV100435210; called by muse, mutect2
- TP53 | c.307dup p.Y103Lfs*46 | Frame Shift Ins (INS) | VAF 38/118 reads (32%) | catalogued as COSV53205932; called by mutect2, pindel, varscan2
- TRIB1 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV100322322; called by muse, mutect2
- UNC93A | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 89/257 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100022922; called by muse, mutect2, varscan2
- VRTN | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.043); catalogued as rs138416499; called by muse, mutect2, varscan2
- ZNF644 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs937387655, COSV100494210; called by muse, mutect2, varscan2
- ADAM29 | c.2021dup p.K675Efs*25 | Frame Shift Ins (INS) | VAF 19/33 reads (58%) | called by mutect2, pindel, varscan2
- CAPN12 | c.238_240del p.E80del | In Frame Del (DEL) | VAF 10/45 reads (22%) | called by mutect2, pindel, varscan2
- CST9 | c.85_99delinsA p.W29Rfs*5 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by pindel, varscan2*
- ABCA12 | c.1870C>T p.L624= (on ENST00000272895 / NM_173076.3; = p.L306= on NM_015657.3) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV99787779; called by muse, mutect2, varscan2
- ABCC1 | c.3036G>A p.T1012= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs751467717, COSV60682255; called by muse, mutect2
- C6orf118 | c.309G>A p.A103= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as rs1311476635, COSV100023920; called by muse, mutect2, varscan2
- CARMIL2 | c.2055G>A p.P685= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs371663153; called by muse, mutect2, varscan2
- CDS1 | c.216C>A p.L72= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV99880297; called by muse, mutect2, varscan2
- DENND2B | c.414G>A p.T138= | Silent (SNP) | VAF 10/101 reads (10%) | catalogued as rs1370938884, COSV58208349; called by muse, mutect2, varscan2
- FYCO1 | c.1551C>T p.F517= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV99945049; called by muse, mutect2, varscan2
- GRM5 | c.1239C>T p.N413= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100549715; called by muse, mutect2, varscan2
- HPCAL1 | c.138C>T p.D46= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs778319187, COSV57144276; called by muse, mutect2, varscan2
- IQCH | c.2766C>A p.I922= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs763963892, COSV100245263; called by muse, mutect2, varscan2
- LOXL3 | c.333C>T p.N111= | Silent (SNP) | VAF 24/87 reads (28%) | catalogued as COSV99283885; called by muse, mutect2, varscan2
- MAGI2 | c.294C>T p.V98= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV100831934; called by muse, mutect2, varscan2
- MINAR1 | c.2706C>T p.T902= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs767051433, COSV100548562; called by muse, mutect2, varscan2
- OR4K1 | c.840C>A p.P280= | Silent (SNP) | VAF 5/82 reads (6%) | called by muse, mutect2
- OR5D16 | c.417C>G p.S139= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV101003799, COSV65722376; called by muse, mutect2, varscan2
- PLOD1 | c.1887C>T p.P629= | Silent (SNP) | VAF 24/50 reads (48%) | catalogued as rs1359830439, COSV99537489; called by muse, mutect2, varscan2
- PRAMEF17 | c.1155C>T p.R385= | Silent (SNP) | VAF 93/221 reads (42%) | catalogued as rs748804075, COSV65816666; called by muse, mutect2, varscan2
- RFT1 | c.1560G>A p.E520= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs369800703; ClinVar: likely benign; called by muse, mutect2, varscan2
- RSF1 | c.4305C>G p.V1435= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV100406788; called by muse, mutect2, varscan2
- SERPINA4 | c.1050C>T p.G350= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100096865; called by mutect2, varscan2
- SHANK2 | c.3978C>T p.N1326= | Silent (SNP) | VAF 12/196 reads (6%) | catalogued as rs370885363; called by muse, mutect2
- TFAP2B | c.1104G>A p.T368= | Silent (SNP) | VAF 75/174 reads (43%) | catalogued as COSV53829206, COSV99540895; called by muse, mutect2, varscan2
- THBS4 | c.1938C>T p.V646= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs769136767, COSV63470357; called by muse, mutect2, varscan2
- TSHZ3 | c.108G>A p.T36= | Silent (SNP) | VAF 24/44 reads (55%) | catalogued as rs191399852, COSV53665533, COSV53669840; called by muse, mutect2, varscan2
- WHRN | c.216C>T p.F72= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV99469675; called by muse, mutect2, varscan2
- YEATS2 | c.1515G>A p.Q505= | Silent (SNP) | VAF 43/93 reads (46%) | catalogued as COSV100527360; called by muse, mutect2, varscan2
- HTR4 | c.1077-969G>C | Intron (SNP) | VAF 4/19 reads (21%) | catalogued as rs200928076, COSV100086924; called by muse, mutect2, varscan2
- LFNG | chr7:2518597 del AGGTA | 5'Flank (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
